MMRF case MMRF_2380 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d7d3840a-b1bc-4ab4-8805-5c4bc4c6f354

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.5 years (25,381 days); ISS stage: III; Days to last known disease status: 729 days (2.0 years); Days to last follow up: 729 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 177 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 547 days (1.5 years); Days to treatment end: 631 days (1.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Third line of therapy; Days to treatment start: 659 days (1.8 years); Days to treatment end: 659 days (1.8 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 661 days (1.8 years); Days to treatment end: 661 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 4 (ECOG 1): M Protein 4.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2947 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.6 mg/dL; Immunoglobulin G 57.6 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 16.1 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 236 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 11.7 g/dL; Glucose 4.07 mmol/L; C-Reactive Protein 0.26 mg/dL.
- Day 177 (ECOG 1): Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 282 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.93 mmol/L.
- Day 380 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 4.29 mmol/L.
- Day 443 (ECOG 1): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 4.9 mmol/L.
- Day 541 (ECOG 1): M Protein 1.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.84 mg/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 5.06 mmol/L.
- Day 627 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 5 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.24 mmol/L.
- Day 729 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 5.87 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 371 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day 4: Weight: 79 kg; Height: 183 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2380_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 4 days.
- Sample MMRF_2380_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 4 days.
